Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A4B0, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A4B0-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession: ✓
Physician:

PROCEDURE

Right thyroid lobectomy.

SPECIMEN:

- A. Right lobe of thyroid. - Frozen section.
- B. Left lobe of thyroid.

HISTORY

Thyroid nodule.

GROSS

A. Received fresh for frozen section diagnosis in a container labeled "right lobe of thyroid" is a thyroid lobe (6.5 x 4.5 x 3.8 cm, 52 g). The lobe has a 4.5 cm in greatest dimension discrete nodule with a uniform firm tan-red cut surface adjacent to a 2.8 cm in diameter nodule with a 1-3 mm thick fibrous wall, spongy brown tissue at the periphery and a 1.6 cm in diameter eccentric cyst containing old brown blood. Compressed thyroid parenchyma at the periphery of the lobe has a uniform red-brown cut surface. Smears are prepared. A representative section of the cystic lesion is submitted for the

Ink code:

Blue - isthmus margin
Black - lobe margin

- FS1. Frozen section control smaller cystic lesion.
- FS2. Frozen section control larger solid tumor mass.

- 1-8. Cystic nodule with nearest margins.
- 9-12. Representative sections from large solid nodule with margin.

B. Received in formalin in a container labeled "left lobe of thyroid" is a lobe of thyroid (4.5 x 2.3 x 1.1 cm, 5 g). The red-brown parenchyma has two firm tan and gray nodules up to 0.8 cm in diameter with ill-defined borders. The margins are marked with black ink. The specimen is serially sectioned and submitted in its entirety in four cassettes.

ICD - 0 - 3

Carcinoma, papillary, follicular variant
8340/3

Site: thyroid, nos C73.9

hw
10/1/12

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

FROZEN SECTION DIAGNOSIS

A. Suspicious for papillary thyroid carcinoma.

MICROSCOPIC

See diagnosis.

DIAGNOSIS

A. Right lobe of thyroid, right thyroidectomy (52 g):
Papillary thyroid carcinoma (see comment).

B. Left lobe of thyroid, left thyroidectomy (5 g):
Papillary thyroid carcinoma (see comment).

COMMENT

THYROID CARCINOMA SUMMARY:

PROCEDURE: Total thyroidectomy.

SPECIMEN INTEGRITY: The specimen is submitted in two parts: right thyroid lobe (part A) and left thyroid lobe (part B).

SPECIMEN SIZE: 6.5 x 4.5 x 3.8 cm, 52 g; part A; 4.5 x 2.3 x 1.1 cm, 5 g, part B.

TUMOR FOCALITY: Multifocal (numerous foci, involving both parts A and B, up to 1.0 cm in greatest dimension).

TUMOR LATERALITY: Bilateral.

TUMOR SIZE: Multiple foci, up to 1.0 cm in greatest dimension.

HISTOLOGIC TYPE: Papillary thyroid carcinoma, follicular variant. *Per TSS, 100% follicular variant.*

MARGINS: Neoplasm is focally present at the inked margin in part B (slide B3).

LYMPHOVASCULAR INVASION: Not identified.

EXTRATHYROIDAL EXTENSION: Not identified.

OTHER FINDINGS: Nodular hyperplasia.

PATHOLOGIC TNM (AJCC Edition): pT1a,m (multifocal), NX.

*fw
9/5/12*

Note: Case reviewed with

Completed Action List:

* Order by

Printed by:

Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

Type:
Date:
Status:
Title:
Encounter info:

Printed by:
Printed on:

I/PAA Discrepancy		X

Source: NCI Genomic Data Commons file 58977291-7955-4596-a25f-2c076b09e5e9 (TCGA-FY-A4B0.513126F2-4AAB-464F-89FB-84202C2853AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).